Somatic mutation profile of tumor specimen TARGET-10-PAPEMZ-09A (aliquot TARGET-10-PAPEMZ-09A-01D) from TARGET case TARGET-10-PAPEMZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,674 days).
Specimen TARGET-10-PAPEMZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 123cbd58-337a-4745-95e7-07a2f123520d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPEMZ-14A (Bone Marrow Normal), aliquot TARGET-10-PAPEMZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d38b84e7-2aef-4dc5-9bbe-d27daf79afcc

The open-access MAF lists 27 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 5, Silent 4, Splice Region 1, 3'UTR 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.2280C>T p.N760= | Splice Region (SNP) | VAF 9/88 reads (10%) | catalogued as COSV52164032; called by muse, mutect2, varscan2
- BICC1 | c.623T>C p.M208T | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.095); catalogued as COSV54064073; called by muse, mutect2, varscan2
- GAS6 | c.1726G>A p.V576M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs374910916; called by muse, mutect2, varscan2
- H3C2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV52518637, COSV52519594, COSV99451261; called by muse, mutect2
- HEMK1 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51751672; called by muse, mutect2
- IGHV1-69 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs548679262; called by muse, mutect2, varscan2
- KCNV2 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs1036473671, COSV66055537; called by muse, mutect2, varscan2
- KLK6 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.154); catalogued as rs755504009, COSV100037885; called by muse, mutect2, varscan2
- PLCB4 | c.3125A>C p.H1042P | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1459856077; called by muse, mutect2, varscan2
- SPINK5 | c.1174G>C p.D392H | Missense Mutation (SNP) | VAF 5/121 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56250197, COSV56250809; called by muse, mutect2
- WDR37 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1174893986; called by muse, mutect2, varscan2
- XRCC6 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs759844857, COSV63753062; called by muse, mutect2, varscan2
- FNTB | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- KDM4E | c.608T>G p.F203C | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SPINK5 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.067); called by muse, mutect2
- DTX3L | c.1596C>T p.S532= | Silent (SNP) | VAF 22/225 reads (10%) | catalogued as rs370064697; called by muse, mutect2, varscan2
- ILDR2 | c.1776G>A p.P592= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs1220063500; called by muse, mutect2
- NR2F1 | c.684C>T p.F228= | Silent (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- UGT2B7 | c.207A>G p.S69= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- CRISP2 | c.515+117G>A | Intron (SNP) | VAF 30/70 reads (43%) | catalogued as rs779621505, COSV59257376; called by muse, mutect2, varscan2
- DPPA3P2 | n.351C>T | RNA (SNP) | VAF 44/176 reads (25%) | catalogued as rs1309642057; called by muse, mutect2
- DST | c.4297-1666C>T | Intron (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- HFE | c.*157C>T | 3'UTR (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- IGFBP2 | c.673-25C>G | Intron (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2
- MPPED2 | c.536+108C>T | Intron (SNP) | VAF 39/81 reads (48%) | catalogued as rs1324499101; called by muse, mutect2, varscan2
- OR2W1 | c.-36C>G | 5'UTR (SNP) | VAF 4/65 reads (6%) | catalogued as rs753857554; called by muse, mutect2
- PAICS | c.-51-29G>A | Intron (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
